Somatic mutation profile of tumor specimen TCGA-43-6647-01A (aliquot TCGA-43-6647-01A-11D-1817-08) from TCGA case TCGA-43-6647, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.5 years (25,378 days).
Specimen TCGA-43-6647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a324b5c6-1af2-4d82-a099-651259c3e7b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-6647-10A (Blood Derived Normal), aliquot TCGA-43-6647-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3d741c4-b6a0-4a75-8ff7-e166275aca67

The open-access MAF lists 170 somatic variants for this specimen: 127 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 39, Nonsense Mutation 12, Splice Site 5, Frame Shift Del 4, 5'Flank 2, Intron 1, Splice Region 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1298G>A p.C433Y | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55940191; called by muse, mutect2, varscan2
- ADAMTS20 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67137172; called by muse, mutect2
- ADAMTS9 | c.2194G>C p.V732L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs749080601, COSV55787803; called by muse, mutect2, varscan2
- ADCY9 | c.3152C>G p.S1051C | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53577864, COSV53580174; called by muse, mutect2
- ADGRA1 | c.80T>A p.V27D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1404618310, COSV66931142; called by muse, mutect2, varscan2
- AKAP6 | c.4747T>C p.F1583L | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV55227780; called by muse, mutect2, varscan2
- AMER2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV63439551; called by muse, mutect2
- ANKRD34A | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV60161784; called by muse, mutect2
- AR | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV65962336; called by muse, mutect2
- ARHGAP10 | c.1392-2A>G p.X464_splice | Splice Site (SNP) | VAF 24/516 reads (5%) | catalogued as COSV60604488; called by muse, mutect2
- ARMCX5-GPRASP2 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63438787; called by muse, mutect2, varscan2
- ATL3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV60297798; called by muse, mutect2
- BCL2L1 | c.679G>T p.G227C (on ENST00000307677 / NM_001317919.2; = p.G164C on NM_001191.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56969007; called by muse, mutect2, varscan2
- BFSP1 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV64901487; called by muse, mutect2
- BIRC6 | c.14416G>A p.E4806K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70204094; called by muse, mutect2, varscan2
- BTNL8 | c.859G>A p.A287T (on ENST00000340184 / NM_001040462.3; = p.R330H on NM_024850.2) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs768102519, COSV51460840; called by muse, mutect2, varscan2
- C16orf86 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV54753083; called by muse, mutect2
- CACNA2D1 | c.545A>C p.E182A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV62389007; called by muse, mutect2, varscan2
- CALML5 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66702686; called by muse, mutect2, varscan2
- CCDC14 | c.2194A>G p.N732D (on ENST00000488653; = p.N684D on NM_022757.5) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV59947162; called by muse, mutect2, varscan2
- CCNB3 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV52078124; called by muse, mutect2, varscan2
- CD1A | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs760559991, COSV56863654; called by muse, mutect2, varscan2
- CDIN1 | c.525G>T p.E175D (on ENST00000437989; = p.E77D on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.436); catalogued as COSV57710431, COSV57713733; called by muse, mutect2
- CENPE | c.7912G>C p.E2638Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV54387430; called by muse, mutect2
- CEP104 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65512714; called by muse, mutect2, varscan2
- CLGN | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 14/324 reads (4%) | catalogued as COSV57775997; called by muse, mutect2
- CLMN | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV54186742; called by muse, mutect2
- COL16A1 | c.2380-1G>A p.X794_splice | Splice Site (SNP) | VAF 13/223 reads (6%) | catalogued as COSV54702583, COSV54711867; called by muse, mutect2
- COL7A1 | c.4321C>T p.P1441S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60401174; called by muse, mutect2
- CRABP2 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | catalogued as COSV63959101; called by muse, mutect2, varscan2
- CUX1 | c.3838C>A p.Q1280K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99471249; called by muse, mutect2, varscan2
- DBF4B | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV59262861; called by muse, mutect2, varscan2
- DCAF12L2 | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV63583746; called by muse, mutect2, varscan2
- DDX1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51842413; called by muse, mutect2, varscan2
- DGKK | c.1848G>T p.W616C | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65709098, COSV65709716; called by muse, mutect2, varscan2
- DGKK | c.1847G>C p.W616S | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053081, COSV65709104; called by muse, mutect2, varscan2
- DMD | c.5800G>C p.E1934Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as CM013377, COSV63741240, COSV63768587; called by muse, mutect2, varscan2
- DPP10 | c.1818C>G p.F606L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as COSV100073724, COSV59713003; called by muse, mutect2, varscan2
- EFNA3 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.273); catalogued as COSV100860819; called by muse, mutect2, varscan2
- ENOX2 | c.1080C>A p.S360R (on ENST00000338144 / NM_001382520.1; = p.S331R on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV100583737, COSV57656526; called by mutect2, varscan2
- EPHA6 | c.3020G>A p.W1007* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV67588961; called by muse, mutect2
- FAM241B | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs777808950, COSV64768738; called by muse, mutect2, varscan2
- FAT4 | c.9943A>G p.K3315E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV58702332; called by muse, mutect2, varscan2
- FLNA | c.5683G>T p.E1895* (on ENST00000369850 / NM_001110556.2; = p.E1887* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV61049010; called by muse, mutect2
- FRK | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 29/192 reads (15%) | catalogued as COSV73384165; called by muse, mutect2, varscan2
- FTH1 | c.115-1G>C p.X39_splice | Splice Site (SNP) | VAF 19/149 reads (13%) | catalogued as COSV56446302; called by muse, mutect2, varscan2
- FUT3 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54607667; called by muse, mutect2, varscan2
- GRM1 | c.1082C>G p.T361S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs1421870663, COSV51254274; called by muse, mutect2, varscan2
- GRM3 | c.710G>C p.R237P | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV64477747; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HEATR4 | c.726C>A p.D242E | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58576284; called by muse, mutect2, varscan2
- HTR7 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV53291580; called by muse, mutect2, varscan2
- HTR7 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV53286390, COSV53291599; called by muse, mutect2, varscan2
- ICAM5 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55748704, COSV99703318, COSV99703420; called by muse, mutect2, varscan2
- INF2 | c.1897C>A p.L633I | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV53035400; called by muse, mutect2
- KIRREL2 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV52879174; called by muse, mutect2
- KLK12 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV51578558; called by muse, mutect2, varscan2
- LAMB4 | c.3915G>A p.A1305= | Splice Region (SNP) | VAF 30/166 reads (18%) | catalogued as rs756445994, COSV52727753; called by muse, mutect2, varscan2
- LRRC14 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs755544856, COSV52881678; called by muse, mutect2, varscan2
- MAGEA1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.839); catalogued as COSV63119076; called by muse, mutect2, varscan2
- MAGEB4 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974935; called by muse, mutect2, varscan2
- MAGED2 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV54498979; called by muse, mutect2
- MAP4K3 | c.1621A>G p.K541E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1398604006, COSV55716803; called by muse, mutect2
- MGAT5B | c.1470G>C p.E490D (on ENST00000569840 / NM_001199172.2; = p.E488D on NM_144677.3) | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV56934715; called by muse, mutect2
- MMP1 | c.521T>C p.F174S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278303383, COSV59511391; called by muse, mutect2
- MYH4 | c.4721C>T p.S1574F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV55123996; called by muse, mutect2, varscan2
- MYLK | c.4397T>C p.I1466T | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs766722671, COSV60618869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCF2 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62316446; called by muse, mutect2
- NDOR1 | c.1540T>C p.F514L (on ENST00000371521 / NM_001144026.3; = p.F507L on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61289564; called by muse, mutect2
- NPHS1 | c.1081T>A p.C361S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62289504; called by muse, mutect2
- NUCB2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV60376587; called by muse, mutect2, varscan2
- OR10G8 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs149526223; called by muse, mutect2, varscan2
- OR11A1 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as COSV101010681, COSV101010702; called by muse, mutect2
- OR51F1 | c.934A>G p.M312V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58578933, COSV58580533; called by muse, mutect2
- OR51T1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as rs751267991, COSV59027430; called by muse, mutect2
- OR52E2 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV58613299; called by muse, mutect2, varscan2
- OR5M11 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1165799172, COSV73141974; called by muse, mutect2, varscan2
- OSBPL5 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as rs374824031, COSV55144696; called by muse, mutect2, varscan2
- PAPOLG | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV53184896; called by muse, mutect2, varscan2
- PAPPA2 | c.4681T>A p.Y1561N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV62808005; called by muse, mutect2, varscan2
- PCDHA8 | c.508T>G p.Y170D | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65339531; called by muse, mutect2
- PDCL3 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51810108; called by muse, mutect2, varscan2
- PIGL | c.236-2A>T p.X79_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV56687205; called by muse, mutect2, varscan2
- PIP4K2A | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV100114470; called by muse, mutect2
- PLXNA3 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63755115; called by muse, mutect2, varscan2
- PMS2 | c.538-1G>T p.X180_splice | Splice Site (SNP) | VAF 5/67 reads (7%) | catalogued as CS146160, COSV56223377; called by muse, mutect2
- PPP1R12B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV61121947; called by muse, mutect2, varscan2
- QRFPR | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57679415; called by muse, mutect2
- RCOR2 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV56851116; called by muse, mutect2, varscan2
- RNASE11 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60088062; called by muse, mutect2, varscan2
- RNF17 | c.4175C>G p.A1392G | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55048046; called by muse, mutect2, varscan2
- RTN1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV50740490; called by muse, mutect2
- RYR2 | c.10102G>T p.A3368S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.853); catalogued as COSV63705828; called by muse, mutect2, varscan2
- SAMD3 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV60777098, COSV60777943; called by muse, mutect2, varscan2
- SCN3A | c.5441C>A p.S1814Y | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51819296, COSV51820084; called by muse, mutect2, varscan2
- SHROOM4 | c.2343C>A p.S781R | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56795266; called by muse, mutect2, varscan2
- SLAMF1 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as COSV52501339; called by muse, mutect2, varscan2
- SLC13A1 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV52008568, COSV52015522; called by muse, mutect2, varscan2
- SMAD4 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV61684357, COSV61685996, COSV61688271; called by muse, mutect2
- SMARCA1 | c.513T>A p.F171L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV64413355; called by mutect2, varscan2
- SSX5 | c.508G>C p.E170Q (on ENST00000347757 / NM_175723.1; = p.E211Q on NM_021015.4) | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61256195; called by muse, mutect2
- STAG2 | c.2427G>T p.M809I | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54368940; called by muse, mutect2, varscan2
- STYK1 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV50014740; called by muse, mutect2
- TDRD1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as rs201551896, COSV52594349, COSV52596384; called by muse, mutect2
- TGFBI | c.1295G>C p.R432T | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV59353293; called by muse, mutect2, varscan2
- TGFBR1 | c.926del p.T309Rfs*26 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as COSV66626657; called by mutect2, varscan2
- THSD7B | c.4189G>T p.V1397L (on ENST00000272643; = p.V1395L on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV55724558; called by muse, mutect2, varscan2
- TLR1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58305311; called by muse, mutect2, varscan2
- TMEM205 | c.569A>T p.*190Lext*? | Nonstop Mutation (SNP) | VAF 29/207 reads (14%) | catalogued as COSV55792647; called by muse, mutect2, varscan2
- TMLHE | c.710T>A p.L237Q | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV57688886; called by muse, mutect2, varscan2
- TMOD3 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57945665; called by muse, mutect2
- TNKS2 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as COSV65416522; called by muse, mutect2, varscan2
- TNS1 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99410528; called by muse, mutect2, varscan2
- TPCN1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs955610654, COSV100136997, COSV59238649; called by muse, mutect2, varscan2
- TRIM49 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV61671642; called by muse, mutect2, varscan2
- TRIM49 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV61671648; called by muse, mutect2, varscan2
- TSC2 | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV54775622; called by muse, mutect2
- TSN | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67605796; called by muse, mutect2
- TTN | c.5925A>C p.E1975D (on ENST00000591111; = p.E1929D on NM_003319.4) | Missense Mutation (SNP) | VAF 32/241 reads (13%) | PolyPhen probably damaging (0.99); catalogued as COSV60264964; called by muse, mutect2, varscan2
- VBP1 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV53973505; called by muse, mutect2, varscan2
- ZIC5 | c.1952A>G p.E651G | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV57438690; called by muse, mutect2, varscan2
- ZNF536 | c.2917T>A p.Y973N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62831582; called by muse, mutect2, varscan2
- ZNF536 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV62831590; called by muse, mutect2
- ZNF77 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV58822509; called by muse, mutect2, varscan2
- IGKV3-11 | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TNRC6A | c.2409del p.W804Gfs*99 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- ZNF677 | c.589del p.A197Hfs*48 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.465G>T p.V155= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV52270014, COSV52270626; called by muse, mutect2, varscan2
- BCL2L1 | c.678G>C p.L226= (on ENST00000307677 / NM_001317919.2; = p.L163= on NM_001191.4) | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100304740, COSV56969021; called by muse, mutect2
- BET1 | c.351G>T p.L117= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55993376; called by muse, mutect2, varscan2
- BTN1A1 | c.564A>T p.T188= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV55069048; called by muse, mutect2
- C6orf118 | c.1023C>T p.L341= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs199716970, COSV57817851; called by muse, mutect2, varscan2
- CENPE | c.4068G>T p.T1356= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV54387448; called by muse, mutect2, varscan2
- CLCN4 | c.1026G>T p.G342= | Silent (SNP) | VAF 41/263 reads (16%) | catalogued as COSV101073780; called by muse, mutect2, varscan2
- CLECL1 | c.210C>T p.V70= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV59931985; called by muse, mutect2, varscan2
- COL7A1 | c.4320C>T p.P1440= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV60401188; called by muse, mutect2
- CPSF3 | c.1053T>C p.G351= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV53011248; called by muse, mutect2, varscan2
- DACT1 | c.2469C>G p.L823= | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as COSV60022805; called by muse, mutect2, varscan2
- DLGAP3 | c.570G>T p.P190= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99332050; called by muse, mutect2, varscan2
- DMBT1 | c.6888G>C p.T2296= (on ENST00000338354 / NM_001377530.1; = p.T1539= on NM_004406.3) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV57555836; called by muse, mutect2
- DOCK11 | c.6187C>A p.R2063= | Silent (SNP) | VAF 25/230 reads (11%) | catalogued as COSV99353626; called by muse, mutect2, varscan2
- FOXR2 | c.96G>A p.L32= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV59259338; called by muse, mutect2, varscan2
- FZD10 | c.1287G>A p.T429= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs565696929, COSV57475190; called by muse, mutect2
- HDX | c.240C>T p.I80= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV52975349, COSV52981559; called by muse, mutect2, varscan2
- IL21R | c.231C>A p.A77= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV61972019; called by muse, mutect2, varscan2
- LRTM2 | c.909C>T p.S303= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs371056648; called by muse, mutect2, varscan2
- MUC16 | c.41649C>T p.S13883= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1168460424, COSV66695558; called by muse, mutect2
- MUC21 | c.1680C>T p.S560= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1490470208, COSV66221540; called by muse, mutect2
- NEXMIF | c.1089A>G p.Q363= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV50075988; called by muse, mutect2, varscan2
- OR13F1 | c.135G>T p.L45= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV58252388; called by muse, mutect2, varscan2
- OR6M1 | c.921C>A p.T307= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs753562902, COSV58434458; called by muse, mutect2, varscan2
- OSR1 | c.753G>C p.T251= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs1327712465, COSV55346228; called by muse, mutect2, varscan2
- PCNX1 | c.6534A>C p.S2178= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV53099755; called by muse, mutect2
- PDE4D | c.1320A>T p.P440= (on ENST00000340635 / NM_001104631.2; = p.P304= on NM_006203.4) | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV57719981; called by muse, mutect2, varscan2
- PER1 | c.2562C>T p.C854= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57921407; called by muse, mutect2
- PGAP6 | c.1867C>T p.L623= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV51741682; called by muse, mutect2, varscan2
- PGK2 | c.633A>T p.I211= | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as COSV59163230, COSV59165113; called by muse, mutect2
- RBM45 | c.1275A>G p.S425= (on ENST00000616198 / NM_001365579.1; = p.S423= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs749506136, COSV53722101; called by muse, mutect2, varscan2
- RGP1 | c.384G>T p.R128= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100960189; called by muse, mutect2, varscan2
- SCN9A | c.2617T>C p.L873= (on ENST00000303354; = p.L862= on NM_002977.3) | Silent (SNP) | VAF 32/205 reads (16%) | catalogued as COSV57620274; called by muse, mutect2, varscan2
- TTC7B | c.198C>T p.A66= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV60636821; called by muse, mutect2, varscan2
- UEVLD | c.1017A>T p.S339= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as COSV57876467; called by muse, mutect2, varscan2
- USP15 | c.2490A>T p.V830= (on ENST00000280377 / NM_001351159.2; = p.V801= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV54796870; called by muse, mutect2, varscan2
- WT1 | c.912C>A p.S304= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV60079509, COSV60082832; called by muse, mutect2, varscan2
- ZFPM2 | c.3231G>T p.S1077= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101022943, COSV65875307; called by muse, mutect2, varscan2
- ZNF816 | c.516T>C p.T172= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV54412113; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722993 C>A | 5'Flank (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100544738, COSV104403478; called by muse, mutect2, varscan2
- MIR513C | n.59C>A | RNA (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- SGK1 | chr6:134177726 del G | 5'Flank (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- SLC41A3 | c.1366+75G>A | Intron (SNP) | VAF 17/107 reads (16%) | catalogued as COSV100259572; called by muse, mutect2, varscan2
